Somatic mutation profile of tumor specimen 0DTC5Z from CCDI case PBCJEN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 15.6 years (5,709 days).
Specimen 0DTC5Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fde37d36-4249-4dd9-99b9-7c9656c4581b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTC5S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80c840fb-a58c-4928-8a83-3f04cac0ff04

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Nonsense Mutation 6, Intron 3, Splice Site 1, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.439del p.V147Lfs*23 | Frame Shift Del (DEL) | VAF 72/504 reads (14%) | catalogued as rs1567553924, COSV52675604, COSV52980910; ClinVar: pathogenic; called by mutect2, varscan2
- WAC | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 58/1254 reads (5%) | catalogued as rs1057518233, COSV61567167; ClinVar: pathogenic; called by muse, mutect2
- AXL | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 63/762 reads (8%) | catalogued as rs1400603712; called by muse, mutect2
- CASR | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 44/898 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.35); catalogued as rs1553766930, CM123753, COSV56133716; ClinVar: uncertain significance; called by muse, mutect2
- COL4A4 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 54/974 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100306458; called by muse, mutect2
- DCST1 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 46/857 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs780909658, COSV55057242, COSV55061157; called by muse, mutect2
- FAM13C | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 68/1268 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs200555371; called by muse, mutect2
- KIF1A | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 65/655 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs373042822; ClinVar: uncertain significance; called by muse, mutect2
- KRTAP2-3 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760379760; called by muse, mutect2
- LAMA2 | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 70/1340 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV70352685; called by muse, mutect2
- MAP2 | c.2905G>T p.E969* | Nonsense Mutation (SNP) | VAF 82/1612 reads (5%) | catalogued as COSV52286537; called by muse, mutect2
- METTL6 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 48/1059 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV101085075; called by muse, mutect2
- OR10H1 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 43/968 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as rs569257281; called by muse, mutect2
- PLEC | c.11563G>T p.E3855* (on ENST00000322810 / NM_201380.4; = p.E3745* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 23/411 reads (6%) | catalogued as COSV59641689, COSV59705192; called by muse, mutect2
- PTPRF | c.3875C>T p.P1292L | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs763328337, COSV100740763, COSV63448725; called by muse, mutect2
- ROBO1 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 61/792 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs531923100, COSV71968487; called by muse, mutect2
- SEMA3G | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.8); catalogued as rs371297669, COSV51598385; called by muse, mutect2
- SHANK3 | c.3671G>A p.R1224H | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs750186589; called by muse, mutect2, varscan2
- TACC2 | c.2347dup p.Q783Pfs*45 | Frame Shift Ins (INS) | VAF 90/393 reads (23%) | catalogued as rs750901207; called by mutect2, varscan2
- VASH1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 64/713 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs780884507, COSV51335214; called by muse, mutect2
- ZNF804A | c.3113T>C p.L1038P | Missense Mutation (SNP) | VAF 38/1043 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56447371; called by muse, mutect2
- ADGRV1 | c.16705G>A p.E5569K | Missense Mutation (SNP) | VAF 64/1058 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.411); called by muse, mutect2
- AKAP6 | c.5068G>C p.E1690Q | Missense Mutation (SNP) | VAF 98/1234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ALPI | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 37/718 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- C4orf54 | c.2735G>A p.R912Q | Missense Mutation (SNP) | VAF 33/598 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- CASTOR2 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 48/614 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- CKAP5 | c.2144C>G p.T715S | Missense Mutation (SNP) | VAF 68/847 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- COL12A1 | c.7256G>A p.S2419N | Missense Mutation (SNP) | VAF 53/1740 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0.028); called by muse, mutect2
- CRACR2A | c.1112T>C p.F371S | Missense Mutation (SNP) | VAF 73/1022 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- EPB41L3 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 19/558 reads (3%) | called by muse, mutect2
- F7 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 32/565 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FIGNL1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 374/1033 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- GALNT13 | c.1234T>A p.W412R | Missense Mutation (SNP) | VAF 34/1213 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- NLRP4 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 24/499 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); called by muse, mutect2
- PXDN | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 40/1024 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.408); called by muse, mutect2
- RMDN1 | c.641+1G>A p.X214_splice | Splice Site (SNP) | VAF 130/1340 reads (10%) | called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 30/1047 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- WAC | c.947C>G p.S316* | Nonsense Mutation (SNP) | VAF 39/1218 reads (3%) | called by muse, mutect2
- XPO1 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 42/1004 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.297); called by muse, mutect2
- ZMIZ2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2
- ZMIZ2 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- CCDC146 | c.534G>A p.L178= | Silent (SNP) | VAF 93/1701 reads (5%) | catalogued as COSV53546754; called by muse, mutect2
- HCAR2 | c.516C>T p.G172= | Silent (SNP) | VAF 61/394 reads (15%) | catalogued as rs202036334, COSV61024240; called by muse, varscan2
- KLHL23 | c.681C>T p.N227= | Silent (SNP) | VAF 32/1218 reads (3%) | called by muse, mutect2
- PCDHA1 | c.1365C>T p.F455= | Silent (SNP) | VAF 53/776 reads (7%) | catalogued as COSV65373026; called by muse, mutect2
- SACS | c.2064C>G p.V688= | Silent (SNP) | VAF 44/835 reads (5%) | catalogued as COSV66544197; called by muse, mutect2
- SUGCT | c.1269C>T p.I423= (on ENST00000335693 / NM_001193313.2; = p.I449= on NM_024728.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/1312 reads (5%) | catalogued as rs762140319, COSV59344992; called by muse, mutect2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 30/1034 reads (3%) | catalogued as rs1267156464; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 9/253 reads (4%) | called by muse, mutect2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 18/640 reads (3%) | called by muse, mutect2
- OR4A47 | c.-66G>T | 5'UTR (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- ZC3H4 | c.492+35C>T | Intron (SNP) | VAF 23/258 reads (9%) | catalogued as rs200531590; called by muse, mutect2, varscan2
